CCDI case PBBWAD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5a17775a-9d53-4afa-b6c7-e1d878daf513

Demographics
Sex at birth: female; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 16.4 years (5,993 days).

Biospecimens (3 samples)
- Sample 0DITSF: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DITT0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DITT7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
